Somatic mutation profile of tumor specimen MMRF_1339_1_BM_CD138pos (aliquot MMRF_1339_1_BM_CD138pos_T1_KBS5U_L05376) from MMRF case MMRF_1339, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.2 years (28,931 days).
Specimen MMRF_1339_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe9e8fc3-8366-46f8-87c3-72c24b898ce7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1339_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1339_1_PB_CD3pos_C2_KBS5U_L05386; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5ab59d0-f48e-4a81-abc5-1643e366222d

The open-access MAF lists 19 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 8, Missense Mutation 4, Intron 4, 5'Flank 1, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL18A1 | c.3363del p.G1122Dfs*17 (on ENST00000359759 / NM_130444.3; = p.G887Dfs*17 on NM_030582.4) | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs775168204; ClinVar: pathogenic; called by pindel, varscan2
- ACP7 | c.522C>G p.N174K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- AZIN2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.028); called by muse, mutect2
- EPB41L4A | c.1965A>T p.E655D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); called by muse, mutect2
- LPCAT2 | c.1017G>A p.M339I | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.495); called by muse, mutect2
- DRC1 | c.531G>A p.E177= | Silent (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- ARHGEF17 | c.*634C>A | 3'UTR (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- DAZAP1 | c.547-180C>G | Intron (SNP) | VAF 3/9 reads (33%) | catalogued as rs938493640; called by muse, mutect2
- DNAJC11 | chr1:6701827 C>A | 5'Flank (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- ERBIN | c.*870C>T | 3'UTR (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- FADS1 | c.*1728G>T | 3'UTR (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- GREM1 | c.*2473A>T | 3'UTR (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- MARK1 | c.*794dup | 3'UTR (INS) | VAF 8/18 reads (44%) | catalogued as rs201671544; called by mutect2, varscan2
- NPEPPS | c.1427-86G>T | Intron (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31460C>A | Intron (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- RAB3B | c.*225C>T | 3'UTR (SNP) | VAF 4/21 reads (19%) | called by mutect2, varscan2
- RSPO1 | c.*232_*233insCATACA | 3'UTR (INS) | VAF 3/20 reads (15%) | called by muse*, pindel
- TMEM179B | c.498+100G>T | Intron (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- VPS13D | c.*2755C>T | 3'UTR (SNP) | VAF 4/42 reads (10%) | catalogued as rs1340958829; called by muse, mutect2
